TCGA case TCGA-GU-A42P — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - UT Southwestern Medical Center at Dallas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ff5b9238-38a7-42b4-9d44-3b8ec9913f6d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 332 days.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 72.7 years (26,546 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 332 days.
   Pathology details: Consistent pathology review: No; Extracapsular extension present: No; Lymph nodes positive: 1; Lymph nodes tested: 14; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; Age at diagnosis: 72.6 years (26,505 days); Days to diagnosis: -41 days; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.
3. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2a.

Follow-up (2 entries)
- Days to follow up: 195 days; Disease response: Tumor Free.
- Days to follow up: 332 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 183 cm; BMI: 23.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 38; Tobacco smoking quit year: 1986; Age at onset: 9.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Cervical Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GU-A42P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-GU-A42P-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-GU-A42P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GU-A42P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Retired; Tobacco smoking history indicator: 3; Tobacco smoking age started: 9; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall NOS; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Cystectomy; Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2a; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No.
- Stage record, Gleason grading: Gleason score: 6.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Patient had synchronous prostate cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 332 days; disease-specific survival: no event (censored), 332 days; progression-free interval: no event (censored), 332 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GU-A42P-01A-11D-A23T-01): tumor purity 0.8, ploidy 5.31, whole-genome doublings 2.
